Somatic mutation profile of tumor specimen 0DS101 from CCDI case PBCGET, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 17.7 years (6,459 days).
Specimen 0DS101: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb8ae785-b7ca-4c9c-a083-cc340041bd12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS0Z8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b381cd14-7864-4596-a4ea-7ec81e354f58

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 3'UTR 3, Intron 3, Silent 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE2 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs770972052, COSV59692221; called by muse, mutect2, varscan2
- AFF1 | c.3589C>T p.R1197* | Nonsense Mutation (SNP) | VAF 468/824 reads (57%) | catalogued as COSV57123051; called by muse, mutect2, varscan2
- ANKRD62 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 82/2075 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs999033599; called by muse, mutect2
- BCAP31 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 125/671 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs782574376; called by muse, mutect2, varscan2
- FGFR1 | c.1638C>G p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 225/319 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58329537, COSV58330551; called by muse, mutect2, varscan2
- KMT2B | c.4459C>T p.R1487C | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs774736378, COSV99719069; called by muse, mutect2, varscan2
- TMEM215 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 184/435 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.872); catalogued as rs201917188, COSV61363184, COSV61363931; called by muse, mutect2, varscan2
- ACTL7A | c.1275C>A p.H425Q | Missense Mutation (SNP) | VAF 171/514 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- GRIA2 | c.883-1G>A p.X295_splice | Splice Site (SNP) | VAF 80/816 reads (10%) | called by muse, mutect2
- PTEN | c.853del p.E285Kfs*6 | Frame Shift Del (DEL) | VAF 38/394 reads (10%) | called by mutect2, varscan2
- PTPRB | c.1844C>A p.S615Y | Missense Mutation (SNP) | VAF 1780/4722 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by mutect2, varscan2
- SEMA3F | c.450C>T p.R150= | Silent (SNP) | VAF 48/257 reads (19%) | catalogued as rs939351843; called by muse, mutect2, varscan2
- CALN1 | c.*55C>T | 3'UTR (SNP) | VAF 45/108 reads (42%) | catalogued as rs747229209, COSV61134784; called by muse, mutect2, varscan2
- LCE2D | c.*63C>A | 3'UTR (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2, varscan2
- RPRD1A | c.789+1249G>A | Intron (SNP) | VAF 377/922 reads (41%) | catalogued as rs932888604; called by muse, mutect2, varscan2
- SCN7A | c.2157+72T>C | Intron (SNP) | VAF 77/137 reads (56%) | called by muse, mutect2, varscan2
- SPHK1 | c.-63G>A | 5'UTR (SNP) | VAF 120/343 reads (35%) | called by muse, mutect2, varscan2
- SRR | c.*982T>C | 3'UTR (SNP) | VAF 43/243 reads (18%) | catalogued as rs1292527686; called by muse, mutect2, varscan2
- TBC1D9B | c.2864-68C>G | Intron (SNP) | VAF 13/65 reads (20%) | catalogued as rs420950; called by muse, mutect2, varscan2
